MMRF case MMRF_1706 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0ed5c242-5432-462e-9fcb-13e4b6460840

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.6 years (24,341 days); ISS stage: I; Days to last known disease status: 1,181 days (3.2 years); Days to last follow up: 1,181 days (3.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 105 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 116 days; Days to treatment end: 116 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 160 days; Days to treatment end: 162 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 163 days; Days to treatment end: 163 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 165 days; Days to treatment end: 165 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 265 days; Days to treatment end: 475 days (1.3 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 0): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 8.74 g/L; Immunoglobulin A 6.79 g/L; Immunoglobulin M 0.66 g/L; Beta 2 Microglobulin 3.1 µg/mL; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 7.71 ×10⁹/L; Absolute Neutrophil 7.13 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 87 µmol/L; Calcium 2.29 mmol/L; Albumin 36 g/L; Total Protein 6.8 g/dL; Glucose 9.4 mmol/L; C-Reactive Protein 4.12 mg/dL.
- Day 84 (ECOG 0): M Protein 4 g/dL; Immunoglobulin G 7.03 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 5.22 ×10⁹/L; Absolute Neutrophil 4.41 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 83 µmol/L; Calcium 2.48 mmol/L; Albumin 37.9 g/L; Total Protein 6.3 g/dL; Glucose 9.9 mmol/L.
- Day 196 (ECOG 1): M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 6.22 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 7.26 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 109 ×10⁹/L; Creatinine 71 µmol/L; Calcium 2.26 mmol/L; Albumin 31 g/L; Total Protein 5.4 g/dL; Glucose 8.3 mmol/L.
- Day 292 (ECOG 1): M Protein 5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.93 mg/dL; Immunoglobulin G 7.55 g/L; Immunoglobulin A 1.6 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 3.5 µg/mL; Lactate Dehydrogenase 1.88 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 3.03 ×10⁹/L; Absolute Neutrophil 2.13 ×10⁹/L; Platelets 82 ×10⁹/L; Creatinine 75 µmol/L; Calcium 2.22 mmol/L; Albumin 31 g/L; Total Protein 5.3 g/dL; Glucose 6.4 mmol/L.
- Day 378 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.95 mg/dL; Immunoglobulin G 7.37 g/L; Immunoglobulin A 2.19 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 2.9 µg/mL; Lactate Dehydrogenase 1.62 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 1.55 ×10⁹/L; Absolute Neutrophil 0.83 ×10⁹/L; Platelets 49 ×10⁹/L; Creatinine 87 µmol/L; Calcium 2.24 mmol/L; Albumin 35 g/L; Total Protein 5.8 g/dL; Glucose 5.6 mmol/L.
- Day 455 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.28 mg/dL; Immunoglobulin G 7.91 g/L; Immunoglobulin A 3.37 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 1.5 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 1.05 ×10⁹/L; Absolute Neutrophil 0.46 ×10⁹/L; Platelets 34 ×10⁹/L; Creatinine 78 µmol/L; Calcium 2.22 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 6.6 mmol/L.
- Day 552 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 8.26 g/L; Immunoglobulin A 2.49 g/L; Immunoglobulin M 0.5 g/L; Lactate Dehydrogenase 1.97 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.64 ×10⁹/L; Platelets 65 ×10⁹/L; Creatinine 82 µmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 6.6 mmol/L.
- Day 621 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 6.71 g/L; Immunoglobulin A 2.47 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 1.77 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.79 ×10⁹/L; Platelets 95 ×10⁹/L; Creatinine 94 µmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 5.3 mmol/L.
- Day 733 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Lactate Dehydrogenase 1.8 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 105 ×10⁹/L; Creatinine 84 µmol/L; Calcium 2.51 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 5.4 mmol/L.
- Day 817 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 6.75 g/L; Immunoglobulin A 2.3 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 2.6 µg/mL; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.53 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 88 µmol/L; Calcium 2.37 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 5 mmol/L.
- Day 901 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.73 mg/dL; Immunoglobulin G 6.59 g/L; Immunoglobulin A 2.34 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3.04 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 83 µmol/L; Calcium 2.27 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 7.7 mmol/L.
- Day 985 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.01 mg/dL; Immunoglobulin G 6.69 g/L; Immunoglobulin A 2.56 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 3.3 µg/mL; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 84 µmol/L; Calcium 2.41 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 6.2 mmol/L.
- Day 1,097 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.49 mg/dL; Immunoglobulin G 6.7 g/L; Immunoglobulin A 2.42 g/L; Immunoglobulin M 0.43 g/L; Beta 2 Microglobulin 3.1 µg/mL; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.66 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 82 µmol/L; Calcium 2.34 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 8.6 mmol/L.
- Day 1,181 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.65 mg/dL; Immunoglobulin G 6.86 g/L; Immunoglobulin A 2.26 g/L; Immunoglobulin M 0.53 g/L; Beta 2 Microglobulin 3.7 µg/mL; Lactate Dehydrogenase 6.95 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 6.95 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 78 µmol/L; Blood Urea Nitrogen 6.2 mmol/L; Calcium 2.5 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 7.4 mmol/L.

Other clinical attributes
- Day 0: Weight: 103 kg; Height: 185 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Maternal Grandmother; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Melanoma; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Prostate Cancer.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Melanoma.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_1706_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1706_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
